CGCI case HTMCP-01-16-00783 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/527302b1-aee5-4095-b7f7-cbeb7e41033c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 45.1 years (16,455 days); Year of diagnosis: 2016; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,087 days (3.0 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Axillary lymph nodes; Sites of involvement: Bone, NOS / Soft tissue / Colon, NOS / Stomach / Small intestine / Liver.
   Pathology details: Lymph node involved site: Cervical, NOS.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Axillary; Tumor largest dimension diameter: 1.9 cm.
   Pathology details: Lymph node involved site: Mesenteric.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (4 entries)
- Days to follow up: 0 days; ECOG performance status: 0.
- Days to follow up: 743 days (2.0 years); Disease response: Tumor Free; Imaging type: PET; Imaging result: Indeterminate.
- Days to follow up: 1,087 days (3.0 years); Disease response: Tumor Free; Imaging type: PET; Imaging result: Indeterminate.
- Follow-up contact recording only the day: day -118.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL2 amplification (FISH): Abnormal, NOS.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- BCL6 amplification (FISH): Abnormal, NOS.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Negative; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- TP53 (IHC): Equivocal; Specialized molecular test: P53 > 20%.
- Test (IHC): Negative; Specialized molecular test: EBER.
- Lactate Dehydrogenase 72500 [Blood test normal range upper: 225].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day -118: Comorbidities: HIV/AIDS.
- Day -118: Risk factors: HIV/AIDS.
- Day 0: Weight: 60.3 kg; Height: 170 cm; BMI: 20.9; CD4 count: 21; Haart treatment indicator: Yes; HIV viral load: 132918.

Biospecimens (3 samples)
- Sample HTMCP-01-16-00783-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-16-00783-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-16-00783-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No.
- History of disease: Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Bone; Submitted tumor site: Soft Tissue (muscle  ligaments  subcutaneous); Submitted tumor site: Colon; Submitted tumor site: Stomach; Submitted tumor site: Small intestine; Submitted tumor site: Liver.
- Primary pathology: Extranodal site involvement: 6; Method initial path diagnosis: Biopsy (all types).
- Tests performed: LDH level: 72500; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: Eber; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-16-00783-01A-01E-14095:
- % tumour top: 95
- % tumour bottom: 95

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-16-00783-01A-01S-14095:
- % tumour top: 95
- % tumour bottom: 95
